Somatic mutation profile of tumor specimen MP2PRT-PARNXA-TMP1-A (aliquot MP2PRT-PARNXA-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNXA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,274 days).
Specimen MP2PRT-PARNXA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d0cdd10-7153-4851-8584-a3abe6abf36e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNXA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNXA-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/559a0c77-0e00-4e32-8240-623905b877ce

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 84/348 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- BYSL | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs780032351; called by muse, mutect2, varscan2
- CD70 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 242/585 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs757012345, COSV55565804; called by muse, mutect2, varscan2
- FBN3 | c.6698C>T p.A2233V | Missense Mutation (SNP) | VAF 190/698 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs144400071; called by muse, mutect2, varscan2
- GPHB5 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV58487321; called by muse, mutect2, varscan2
- NAB1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 121/512 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100493092; called by muse, mutect2, varscan2
- NXF3 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 226/262 reads (86%) | SIFT tolerated (0.25); PolyPhen benign (0.382); catalogued as rs1197593015, COSV67704804; called by muse, mutect2, varscan2
- ROS1 | c.5028G>A p.W1676* | Nonsense Mutation (SNP) | VAF 45/264 reads (17%) | catalogued as COSV99055286; called by muse, mutect2, varscan2
- RYR2 | c.7493C>T p.A2498V | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs374191985, CM0910998; ClinVar: uncertain significance / benign; called by muse, mutect2
- SLC5A10 | c.1549G>A p.A517T (on ENST00000395645 / NM_001042450.4; = p.A533T on NM_152351.5) | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs367605069; called by muse, mutect2, varscan2
- ABCC4 | c.2826G>C p.L942F | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCNC | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CEP128 | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETAA1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 143/678 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IGHV1-69 | c.350_351insCCTAGGGC p.R117Sfs*? | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- RWDD2A | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SACS | c.7622C>T p.S2541F | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UAP1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARHGEF26 | c.348C>T p.L116= | Silent (SNP) | VAF 132/600 reads (22%) | called by muse, varscan2
- CSPG4 | c.2271G>A p.E757= | Silent (SNP) | VAF 34/732 reads (5%) | catalogued as rs769725344; called by muse, mutect2
- FAT1 | c.4179C>T p.I1393= | Silent (SNP) | VAF 90/318 reads (28%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1275C>T p.F425= | Silent (SNP) | VAF 94/473 reads (20%) | catalogued as COSV58116516, COSV58141676; called by muse, mutect2, varscan2
- TAS1R2 | c.2424C>T p.F808= | Silent (SNP) | VAF 156/458 reads (34%) | catalogued as rs769223297, COSV64744954, COSV64747180; called by muse, varscan2
- ZNF730 | c.510G>A p.K170= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1436501080; called by muse, mutect2, varscan2
